Gene-level copy-number profile of tumor specimen SM-JU332 from CPTAC case C266664, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen SM-JU332: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 18ddc8f3-b036-44a3-99da-e764ef9227d5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105287 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/a27e1d04-dcd1-43e5-8d00-0b35f5660bf5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 139; copy number 2: 18,442; copy number 3: 20,523; copy number 4: 17,065; copy number 5: 605; copy number 6: 1,096; copy number 7: 381; copy number 8: 84; copy number 9: 12; copy number 10: 9; copy number 12: 13.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr15:63,042,632–63,071,915, 3 genes: TPM1, TPM1-AS, AC079328.2.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr18:46,917,492–47,102,243, 8 genes (within-gene range 0–2): KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2, AC012254.5, AC012254.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 499 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,751,232–1,891,117, 2 genes, copy number 8: NADK, GNB1.
- chr1:6,101,787–6,393,767, 10 genes, copy number 7 (within-gene range 5–7): CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7.
- chr1:12,838,125–12,841,357, 1 gene, copy number 8: PRAMEF30P.
- chr1:25,242,249–25,338,213, 1 gene, copy number 7 (within-gene range 4–7): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes, copy number 7: AL031432.2, RHD, SDHDP6.
- chr3:9,292,588–10,321,112, 50 genes, copy number 8 (within-gene range 6–8): AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3, SETD5, LHFPL4, DUSP5P2, MTMR14, AC022382.2, CPNE9, BRPF1, OGG1, CAMK1, TADA3, ARPC4, ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3, CIDEC, JAGN1, IL17RE, IL17RC, RNU6-882P, AC018809.3, CRELD1, AC018809.1, PRRT3, PRRT3-AS1, AC018809.2, EMC3, EMC3-AS1, CYCSP10, AC022007.1, CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1, VHL, AC034193.1, IRAK2, TATDN2, AC022384.1, LINC00852, GHRL, GHRLOS, AC022384.2, SEC13.
- chr3:11,137,093–12,788,671, 34 genes, copy number 7–12: HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3, TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1, RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17.
- chr5:1,252,006–2,119,926, 30 genes, copy number 8: AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2.
- chr5:23,443,586–23,528,093, 1 gene, copy number 7 (within-gene range 6–7): PRDM9.
- chr5:23,688,927–45,895,970, 308 genes, copy number 7 (broad region; genes not listed).
- chr8:17,469,518–17,800,917, 10 genes, copy number 9 (within-gene range 6–10): ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1.
- chr8:17,748,118–18,097,644, 10 genes, copy number 9–10: RNA5SP256, AC027117.2, AC027117.1, FGL1, AC087273.1, AC087273.2, PCM1, ASAH1, AC124242.1, AC124242.2.
- chr13:74,231,457–74,259,976, 1 gene, copy number 9: LINC00402.
- chr13:76,134,931–76,135,225, 1 gene, copy number 8: RN7SL571P.
- chr17:22,056,587–22,531,392, 21 genes, copy number 7: ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13.
- chr17:77,014,880–77,500,596, 13 genes, copy number 7 (within-gene range 2–7): Metazoa_SRP, SNHG20, SEC14L1, SCARNA16, MIR6516, RNU4-47P, CYCSP40, SEPTIN9-DT, AC068594.1, SEPTIN9, AC111182.1, AC111182.2, MIR4316.
- chr19:43,192,702–43,269,530, 3 genes, copy number 7: PSG4, CEACAMP10, PSG9.

Autosomal genes at a single copy (total copy number 1): 139. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
